Gene-level copy-number profile of tumor specimen TCGA-EE-A29E-06A from TCGA case TCGA-EE-A29E, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 54.7 years (19,991 days).
Specimen TCGA-EE-A29E-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.d268c5aa-fa8b-4221-81c1-d81489223bf0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EE-A29E-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d14d3e21-9095-4780-84f1-bb15dfcca935

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 6,802; copy number 2: 45,060; copy number 3: 6,983; copy number 4: 918; copy number 5: 26; copy number 9: 25.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EE-A29E-06A-11D-A191-01): tumor purity 0.86, ploidy 2.06, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:2,720,469–2,844,095, 1 gene (within-gene range 0–1): PUM3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 51 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:48,831,018–49,848,837, 51 genes, copy number 5–9: CALCOCO2, SUMO2P17, AC068531.1, AC068531.2, ATP5MC1, AC091133.6, UBE2Z, SNF8, AC091133.1, RNU1-42P, AC091133.2, GIP, AC091133.3, IGF2BP1, AC091133.4, Metazoa_SRP, RNU6-826P, AC091133.5, B4GALNT2P1, B4GALNT2, AC069454.1, GNGT2, ABI3, PHOSPHO1, FLJ40194, MIR6129, ZNF652, AC091180.2, AC091180.5, AC091180.4, AC091180.1, PHB, AC091180.3, Y_RNA, EIF4EP2, LINC02075, AC015656.1, NGFR, AC006487.1, MIR6165, AC006487.2, NXPH3, SPOP, SLC35B1, AC015795.1, FAM117A, KAT7, SRP14P3, AC027801.5, TAC4, AC027801.1.

Autosomal genes at a single copy (total copy number 1): 4,381. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
